Surgical pathology report (de-identified scan), TCGA case TCGA-FA-A6HO, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site Asterand, specimen TCGA-FA-A6HO-01A (Primary Tumor).

Surgical Date:

Gross Description: Lymph node is enlarged with 1.5x1x1cm in size, soft, dark brown and gray surface.

Microscopic Description: Tumor architectures are replaced by diffuse pattern. The tumor cells are composed of small or enlarged transformed lymphoid cells with irregular hyperchromatic nuclei. Tumor cells are oval or round in shape with scant cytoplasm. Nucleoli is single or multiple. Mitotic figures are common.

Diagnosis Details: Malignant lymphoma, large B cell, diffuse type.

Comments:

Formatted Path Reports: Diagnosis: Diffuse large B-cell lymphoma

Tumor location: Lymph node, cervical

Tumor size: 1.5 x 1x 1cm

Tumor markers: CD20(+), CD3(-) ✓

ICD-O-3

Lymphoma, diffuse large B-cell
9680/3

Site: Lymph node, cervical
C77.0

JA 6/10/13

Case is (being):	QUALIFIED	UNQUALIFIED

Source: NCI Genomic Data Commons file 68d04db9-3501-4be8-b5cd-f9170b06c27a (TCGA-FA-A6HO.E2645414-D707-419D-B43D-92AE9D56DCD1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).